Somatic mutation profile of tumor specimen TCGA-CR-7402-01A (aliquot TCGA-CR-7402-01A-11D-2012-08) from TCGA case TCGA-CR-7402, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 68.8 years (25,138 days).
Specimen TCGA-CR-7402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49dd61c1-0a40-458a-893b-5eacda2b7de7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7402-10A (Blood Derived Normal), aliquot TCGA-CR-7402-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/481d3c0e-6829-4fe6-9e5f-a826f5a8c3dc

The open-access MAF lists 1,083 somatic variants for this specimen: 821 protein-altering or splice-affecting, 235 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 692, Silent 235, Nonsense Mutation 57, Frame Shift Del 28, Splice Site 27, Intron 10, Splice Region 8, Frame Shift Ins 7, RNA 7, 3'UTR 6, 5'Flank 2, In Frame Del 1.

Variants (750 of 1,083; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs369607332, CM053204, COSV50377641; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5965C>T p.Q1989* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as rs587784170, CM052318, COSV100729619, COSV61778930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 23/40 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- AASDH | c.2065T>A p.S689T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as COSV99221566; called by muse, mutect2, varscan2
- ABCA12 | c.163+2T>A p.X55_splice | Splice Site (SNP) | VAF 21/44 reads (48%) | catalogued as COSV55952204, COSV99790982; called by muse, mutect2, varscan2
- ABCA13 | c.11989G>T p.V3997L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447063; called by muse, mutect2, varscan2
- ABCA13 | c.14368C>A p.L4790M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV101291385; called by muse, mutect2, varscan2
- ABCB1 | c.2681G>C p.G894A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55955657; called by muse, mutect2, varscan2
- ABCC2 | c.191T>A p.L64H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV64971500; called by muse, mutect2, varscan2
- ABCD4 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934475392, COSV100084401; called by muse, mutect2, varscan2
- ABL2 | c.3352G>T p.D1118Y (on ENST00000502732 / NM_007314.4; = p.D1103Y on NM_005158.5) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100772871; called by muse, mutect2, varscan2
- AC020907.6 | c.132C>G p.C44W | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100032743; called by muse, mutect2, varscan2
- AC244197.3 | c.552G>T p.R184S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as CD050455, COSV100558093; called by muse, mutect2, varscan2
- ACADL | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV99284917; called by muse, mutect2, varscan2
- ACAN | c.5949C>A p.D1983E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.952); catalogued as COSV100718693; called by muse, mutect2, varscan2
- ACAP2 | c.2061A>T p.T687= | Splice Region (SNP) | VAF 19/143 reads (13%) | catalogued as COSV100462494; called by muse, mutect2, varscan2
- ACO2 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99347583; called by muse, mutect2, varscan2
- ACSS1 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV100053889; called by muse, mutect2, varscan2
- ACTN2 | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100856895; called by muse, mutect2, varscan2
- ADAM11 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs370482564, COSV52349463; called by muse, mutect2, varscan2
- ADAM17 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176387; called by muse, mutect2, varscan2
- ADAM19 | c.1269T>A p.Y423* | Nonsense Mutation (SNP) | VAF 49/164 reads (30%) | catalogued as COSV99977848; called by muse, mutect2, varscan2
- ADAMTS5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99537561; called by muse, mutect2, varscan2
- ADAMTS9 | c.2408G>A p.G803D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); catalogued as COSV99899888; called by muse, mutect2, varscan2
- ADCY2 | c.2508C>A p.N836K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100603412; called by muse, varscan2
- AFMID | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100015038; called by muse, mutect2, varscan2
- AHCTF1 | c.6010G>T p.A2004S (on ENST00000366508; = p.A1978S on NM_015446.5) | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV100404074; called by muse, mutect2, varscan2
- AHNAK | c.12111C>G p.I4037M | Missense Mutation (SNP) | VAF 98/361 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV99948510; called by muse, mutect2, varscan2
- AHNAK | c.3198G>C p.K1066N | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99948515; called by muse, mutect2, varscan2
- AIRE | c.580A>T p.M194L | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99381278; called by muse, mutect2, varscan2
- AKAP12 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99483916; called by muse, mutect2, varscan2
- AKAP12 | c.3751T>A p.S1251T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99483922; called by muse, mutect2, varscan2
- ALDH1L1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99857205; called by muse, mutect2, varscan2
- ALKBH2 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV99655415; called by muse, mutect2, varscan2
- ALOX12B | c.1673G>C p.R558P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.362); catalogued as COSV100047450; called by muse, mutect2, varscan2
- AMDHD2 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53550816, COSV99566010; called by muse, mutect2, varscan2
- AMER3 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290013370, COSV100366732; called by muse, mutect2, varscan2
- ANK3 | c.115-2A>C p.X39_splice | Splice Site (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99781097; called by muse, mutect2, varscan2
- ANKRD34B | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV58613333; called by muse, mutect2, varscan2
- ANKZF1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100037073, COSV60135139; called by muse, mutect2, varscan2
- ANO4 | c.1890C>A p.N630K (on ENST00000392977 / NM_001286615.2; = p.N595K on NM_178826.4) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.439); catalogued as COSV100153317; called by muse, mutect2, varscan2
- AP4B1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs768636022, COSV99870972; called by muse, mutect2, varscan2
- AP5Z1 | c.2384G>T p.S795I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1266870234, COSV100804187; called by muse, mutect2, varscan2
- APOB | c.9698A>G p.Y3233C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs753419406, COSV99266682; called by muse, mutect2, varscan2
- APOB | c.4255A>T p.T1419S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51941232, COSV99266685; called by muse, mutect2, varscan2
- APOBEC3B | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV100213824; called by muse, mutect2, varscan2
- APPL2 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.389); catalogued as COSV99314971; called by muse, mutect2, varscan2
- ARAP2 | c.620G>C p.S207T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.02); catalogued as COSV100394949; called by muse, mutect2, varscan2
- ARAP3 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs372101887, COSV53355287; called by muse, mutect2, varscan2
- ARHGAP28 | c.1280C>A p.A427D (on ENST00000383472 / NM_001366230.1; = p.A268D on NM_001010000.3) | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV99151142; called by muse, mutect2, varscan2
- ARHGAP35 | c.4270A>G p.I1424V | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV101351327; called by muse, mutect2, varscan2
- ARID1A | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV100252479; called by muse, mutect2, varscan2
- ARL4A | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV100775940; called by muse, mutect2, varscan2
- ARRDC5 | c.909G>T p.W303C (on ENST00000381781; = p.W289C on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV101108217; called by muse, mutect2, varscan2
- ART1 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV99167151, COSV99167212; called by muse, mutect2, varscan2
- ASPH | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs773407540, COSV100727688; called by muse, mutect2, varscan2
- ASTN2 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV100523981, COSV100528998; called by muse, mutect2, varscan2
- ASXL3 | c.3876C>A p.C1292* | Nonsense Mutation (SNP) | VAF 67/119 reads (56%) | catalogued as COSV99325721; called by muse, mutect2, varscan2
- ASZ1 | c.772T>A p.L258M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV52912358, COSV99498151; called by muse, mutect2, varscan2
- ATF1 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100016181; called by muse, mutect2, varscan2
- ATP6V0D2 | c.995C>A p.A332E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99571930; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV99369514; called by muse, mutect2, varscan2
- ATP6V1C1 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV101215088; called by muse, mutect2, varscan2
- ATP8A2 | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54960082, COSV99683035; called by muse, mutect2, varscan2
- AUP1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as rs757009295, COSV51212038; called by muse, mutect2, varscan2
- AVL9 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100594701; called by muse, mutect2, varscan2
- BHMT2 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99670207; called by muse, mutect2, varscan2
- BNC2 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs772675068, COSV66145107; called by muse, mutect2, varscan2
- BOD1L1 | c.2741C>A p.S914* | Nonsense Mutation (SNP) | VAF 36/142 reads (25%) | catalogued as COSV99239898; called by muse, mutect2, varscan2
- BPIFB2 | c.309-1G>T p.X103_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99401547; called by muse, varscan2
- BRINP3 | c.1516A>T p.R506* | Nonsense Mutation (SNP) | VAF 54/184 reads (29%) | catalogued as COSV100819117; called by muse, mutect2, varscan2
- BTNL3 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100732221; called by muse, mutect2, varscan2
- C10orf120 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100271708; called by muse, mutect2, varscan2
- C10orf88 | c.547A>T p.R183W | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100925032; called by muse, mutect2, varscan2
- C10orf99 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs1174018046, COSV100929362; called by muse, mutect2, varscan2
- C12orf29 | c.145A>T p.I49L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100795101; called by muse, mutect2, varscan2
- C1GALT1 | c.873T>A p.Y291* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99777612; called by muse, mutect2, varscan2
- C20orf85 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100959472; called by muse, mutect2, varscan2
- C22orf42 | c.186G>C p.Q62H | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV101173358, COSV101173404; called by muse, mutect2, varscan2
- C2CD5 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV100448899; called by muse, mutect2, varscan2
- C3 | c.3599G>C p.G1200A | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99836979; called by muse, mutect2, varscan2
- C7 | c.2267C>T p.T756I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100496217; called by muse, mutect2, varscan2
- C7orf57 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as rs200433005, COSV100817309, COSV62364505; called by muse, mutect2, varscan2
- C9 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99662301; called by muse, mutect2, varscan2
- C9 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV99662302; called by muse, mutect2, varscan2
- CABIN1 | c.2911-1G>T p.X971_splice | Splice Site (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99573648; called by muse, mutect2, varscan2
- CACHD1 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 114/205 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99262809; called by muse, mutect2, varscan2
- CACNA1A | c.5531A>G p.Y1844C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100802856; called by muse, mutect2, varscan2
- CACNA1D | c.3217C>A p.R1073S (on ENST00000350061 / NM_001128840.3; = p.R1093S on NM_000720.4) | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV55447408, COSV99859069; called by muse, mutect2, varscan2
- CACNA1E | c.5677C>G p.Q1893E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as rs768172934, COSV62381204; called by muse, mutect2
- CACNA1E | c.5827C>T p.P1943S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs549170593, COSV100704124, COSV62419963; called by muse, mutect2, varscan2
- CACNA1I | c.1235T>C p.M412T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100360941; called by muse, mutect2, varscan2
- CACNB2 | c.271G>T p.D91Y (on ENST00000324631 / NM_201596.3; = p.D36Y on NM_000724.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99995456; called by muse, mutect2, varscan2
- CADM1 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100523062; called by muse, mutect2, varscan2
- CADM4 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99731410, COSV99731600; called by muse, mutect2, varscan2
- CAMK2A | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100804598; called by mutect2, varscan2
- CAMSAP2 | c.4046-1G>C p.X1349_splice (on ENST00000236925 / NM_001297707.2; = p.X1338_splice on NM_203459.3) | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99373764; called by muse, mutect2, varscan2
- CAPS2 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs373505414, COSV60824815; called by muse, mutect2, varscan2
- CASP8 | c.412-2A>G p.X138_splice (on ENST00000432109 / NM_033355.3; = p.X170_splice on NM_001228.4) | Splice Site (SNP) | VAF 29/83 reads (35%) | catalogued as COSV51853733; called by muse, mutect2, varscan2
- CCDC14 | c.2518C>A p.H840N (on ENST00000488653; = p.H792N on NM_022757.5) | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100113340; called by muse, mutect2, varscan2
- CCDC38 | c.138G>T p.T46= | Splice Region (SNP) | VAF 16/63 reads (25%) | catalogued as rs139084164, COSV100717751; called by muse, mutect2, varscan2
- CCDC47 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as COSV99854248; called by muse, mutect2, varscan2
- CCK | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100588977, COSV100589059; called by muse, mutect2, varscan2
- CCL8 | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV101126438; called by muse, mutect2, varscan2
- CCNB3 | c.2053A>C p.K685Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.427); catalogued as rs782776724, COSV99329425; called by muse, mutect2, varscan2
- CCT8L2 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100742906, COSV63461758; called by muse, mutect2, varscan2
- CCT8L2 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100742907; called by muse, mutect2, varscan2
- CD163 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV100775993, COSV63137653; called by muse, mutect2, varscan2
- CD226 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs748557039, COSV54612733, COSV54613816; called by muse, mutect2, varscan2
- CD38 | c.149G>T p.W50L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99882895; called by muse, mutect2, varscan2
- CD93 | c.1836G>C p.K612N | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV99849381; called by muse, mutect2, varscan2
- CDC42EP2 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.642); catalogued as COSV99659165; called by muse, mutect2, varscan2
- CDH10 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249602021, COSV52571172, COSV52587577; called by muse, mutect2, varscan2
- CDH11 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs747102834, COSV51774410, COSV51776848, COSV99219561; called by muse, mutect2, varscan2
- CDH20 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752914935, COSV99405942; called by muse, mutect2, varscan2
- CDH23 | c.6017A>G p.Q2006R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99822382; called by muse, mutect2, varscan2
- CDH6 | c.2174C>A p.T725K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.069); catalogued as COSV54065519; called by mutect2, varscan2
- CDK5RAP2 | c.4259G>C p.R1420P | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100575628, COSV62575026; called by muse, mutect2, varscan2
- CEACAM18 | c.436A>G p.S146G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV101140522; called by muse, mutect2, varscan2
- CEACAM7 | c.236T>A p.I79N | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99137300; called by muse, mutect2, varscan2
- CELSR2 | c.4099G>A p.V1367M | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV99604380; called by muse, mutect2, varscan2
- CENPQ | c.587G>T p.R196I | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1193168229, COSV100225809, COSV100225823; called by muse, mutect2, varscan2
- CEP131 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99488672; called by muse, mutect2, varscan2
- CEP350 | c.6531G>C p.E2177D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100854971; called by muse, mutect2
- CETN1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1478884892, COSV100511374; called by muse, mutect2, varscan2
- CFAP36 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100171077; called by muse, mutect2, varscan2
- CFAP45 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as rs748331211, COSV100928638; called by muse, mutect2, varscan2
- CFAP54 | c.8141T>C p.V2714A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100733274; called by muse, varscan2
- CFTR | c.2969C>A p.T990N | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs201761547, COSV99137815; called by muse, mutect2, varscan2
- CHGB | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs772020493, COSV66760725; called by muse, mutect2, varscan2
- CHIT1 | c.416G>T p.W139L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705453; called by muse, mutect2, varscan2
- CHP2 | c.565A>G p.K189E | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100270222; called by muse, mutect2, varscan2
- CHRFAM7A | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100241653; called by muse, mutect2, varscan2
- CIITA | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.076); catalogued as COSV100162338; called by muse, mutect2, varscan2
- CKAP5 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100371084; called by muse, mutect2, varscan2
- CNKSR3 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101527237, COSV101527250; called by muse, mutect2, varscan2
- CNR1 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.029); catalogued as COSV100759271; called by muse, mutect2, varscan2
- CNTRL | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99443056; called by muse, mutect2, varscan2
- COBL | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99473388; called by muse, mutect2, varscan2
- COL11A2 | c.1802G>T p.G601V (on ENST00000341947 / NM_080680.3; = p.G494V on NM_080679.2) | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554296; called by muse, mutect2, varscan2
- COL19A1 | c.1397T>A p.L466Q | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100506912; called by muse, mutect2, varscan2
- COL19A1 | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506914; called by muse, mutect2, varscan2
- COL6A1 | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.296); catalogued as COSV100720348; called by muse, mutect2, varscan2
- COL8A1 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as rs751168494, COSV53730201, COSV99658100; called by mutect2, varscan2
- CPA3 | c.345C>A p.S115R | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99936274; called by muse, mutect2, varscan2
- CPNE4 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.238); catalogued as rs777424494, COSV101456768; called by muse, mutect2, varscan2
- CPNE5 | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 30/62 reads (48%) | catalogued as COSV99783061; called by muse, mutect2, varscan2
- CPSF1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100574676; called by muse, mutect2, varscan2
- CPT1A | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99681412; called by muse, mutect2, varscan2
- CR1 | c.5515C>G p.R1839G | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV100887867, COSV65464203; called by muse, mutect2, varscan2
- CREBZF | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV99476388; called by muse, mutect2, varscan2
- CRISP2 | c.426G>T p.W142C | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189148; called by muse, mutect2, varscan2
- CRISPLD1 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100082230, COSV51553893; called by muse, mutect2, varscan2
- CRLF2 | c.547T>C p.F183L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV101053765; called by muse, mutect2, varscan2
- CRNN | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV99664237; called by muse, mutect2, varscan2
- CRX | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV99704591; called by muse, mutect2, varscan2
- CSMD2 | c.3227G>T p.R1076L | Missense Mutation (SNP) | VAF 169/284 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV53879951, COSV99592538; called by muse, mutect2, varscan2
- CSMD3 | c.10634A>G p.Y3545C (on ENST00000297405 / NM_001363185.1; = p.Y3376C on NM_052900.3) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99840638; called by muse, mutect2, varscan2
- CSMD3 | c.10279C>A p.L3427I (on ENST00000297405 / NM_001363185.1; = p.L3258I on NM_052900.3) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52244890; called by mutect2, varscan2
- CSMD3 | c.5639C>T p.S1880F (on ENST00000297405 / NM_001363185.1; = p.S1776F on NM_052900.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV52235656, COSV99840643; called by muse, mutect2, varscan2
- CSN2 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.529); catalogued as COSV100778801; called by muse, mutect2, varscan2
- CST5 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 78/310 reads (25%) | catalogued as rs1315945258, COSV100489700; called by muse, mutect2, varscan2
- CST8 | c.384G>C p.W128C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99850038; called by muse, mutect2, varscan2
- CSTF2 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.968); catalogued as COSV65895273; called by muse, mutect2
- CTAGE6 | c.1318C>A p.L440I | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs776995739, COSV69917170; called by muse, mutect2, varscan2
- CTNNA2 | c.980G>T p.R327L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100785271; called by muse, mutect2, varscan2
- CUBN | c.8004C>A p.H2668Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.657); catalogued as COSV100913101; called by muse, mutect2, varscan2
- CUBN | c.2225A>T p.Q742L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100913103; called by muse, mutect2, varscan2
- CUBN | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100910622; called by muse, mutect2, varscan2
- CWF19L2 | c.1992G>T p.E664D | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV99979455; called by muse, mutect2, varscan2
- CYB5RL | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839080; called by muse, mutect2, varscan2
- CYLC2 | c.180+2T>C p.X60_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100872498; called by muse, mutect2, varscan2
- CYP2C19 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100990575, COSV64907729; called by muse, mutect2, varscan2
- CYP4F22 | c.846del p.R283Gfs*87 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as COSV54107193; called by mutect2, pindel, varscan2
- DBX2 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as COSV100224417, COSV60337074; called by muse, mutect2, varscan2
- DCLRE1A | c.2110T>C p.Y704H | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV100800427; called by muse, mutect2, varscan2
- DDI1 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV56389021; called by muse, mutect2, varscan2
- DDR1 | c.931A>G p.M311V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV61321764; called by muse, mutect2, varscan2
- DDR2 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as COSV100906218, COSV100906734; called by muse, mutect2, varscan2
- DENND2A | c.2246C>G p.S749C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99326514; called by muse, mutect2
- DGKI | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99935948, COSV99937040; called by muse, mutect2, varscan2
- DGKI | c.1425G>T p.G475= | Splice Region (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99935951; called by muse, mutect2, varscan2
- DICER1 | c.1800C>A p.D600E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100602301; called by muse, mutect2, varscan2
- DIDO1 | c.3022G>T p.V1008L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99826475; called by muse, mutect2, varscan2
- DIRAS1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100053100; called by muse, mutect2, varscan2
- DMBT1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 146/508 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771172162, COSV57553849; called by muse, mutect2, varscan2
- DNAH10 | c.9370G>T p.E3124* (on ENST00000409039; = p.E3063* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101292433; called by muse, mutect2
- DNAH5 | c.8604C>A p.D2868E | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99451826; called by muse, mutect2, varscan2
- DNAH5 | c.4388G>T p.W1463L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99451830; called by muse, varscan2
- DNAH9 | c.1203G>C p.L401F | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as COSV99306890; called by muse, mutect2, varscan2
- DNAH9 | c.6293T>A p.F2098Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868365547, COSV99306893; called by muse, mutect2, varscan2
- DNAI2 | c.1135A>T p.N379Y | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.129); catalogued as COSV100209944; called by muse, mutect2, varscan2
- DNAI4 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100925233; called by muse, mutect2, varscan2
- DOCK10 | c.5889C>A p.D1963E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99290566; called by muse, mutect2, varscan2
- DOCK4 | c.1391G>T p.S464I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101455635; called by muse, varscan2
- DPYD | c.2368A>T p.I790F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100929225; called by muse, mutect2, varscan2
- DPYD | c.2096G>T p.R699M | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100929226; called by muse, mutect2, varscan2
- DSCAML1 | c.5300C>G p.P1767R (on ENST00000321322; = p.P1707R on NM_020693.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100356527; called by muse, mutect2, varscan2
- DSCAML1 | c.3469G>T p.V1157F (on ENST00000321322; = p.V1097F on NM_020693.4) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356529; called by muse, mutect2, varscan2
- DST | c.20274G>T p.R6758S (on ENST00000361203 / NM_001374722.1; = p.R4455S on NM_015548.5) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55000678; called by muse, mutect2, varscan2
- DTD1 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV101079945; called by muse, mutect2, varscan2
- DUSP9 | c.1055A>C p.Q352P | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100720141; called by muse, mutect2, varscan2
- DYRK2 | c.1213A>T p.M405L (on ENST00000344096 / NM_006482.3; = p.M332L on NM_003583.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100165340; called by muse, mutect2, varscan2
- E2F2 | c.9A>T p.Q3H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100674838; called by muse, mutect2, varscan2
- ECT2L | c.1016A>C p.Q339P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100872080; called by muse, mutect2, varscan2
- EEFSEC | c.787-2A>T p.X263_splice | Splice Site (SNP) | VAF 30/140 reads (21%) | catalogued as COSV99629837, COSV99630771; called by muse, mutect2, varscan2
- EFTUD2 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99493996; called by muse, mutect2, varscan2
- EIF4E1B | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100024798; called by muse, mutect2, varscan2
- ELL2 | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as COSV99427668; called by muse, mutect2, varscan2
- ELOA2 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs1313370826, COSV99797245; called by muse, mutect2, varscan2
- ENKUR | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1196146150, COSV100482057; called by muse, mutect2, varscan2
- ENPEP | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256395871, COSV99487856; called by muse, mutect2, varscan2
- ENPP1 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV100719604; called by muse, mutect2, varscan2
- EPHA3 | c.1118G>T p.C373F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100346862; called by muse, mutect2, varscan2
- EPHA5 | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV56651049, COSV99900054; called by muse, mutect2, varscan2
- EPHA6 | c.3128T>C p.V1043A | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.267); catalogued as COSV101064351; called by muse, mutect2, varscan2
- EPHA8 | c.2490G>T p.E830D | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99385259; called by muse, mutect2, varscan2
- ERBB4 | c.380del p.G127Efs*10 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as COSV53551212; called by mutect2, pindel, varscan2
- ERCC6 | c.4276G>C p.D1426H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100876036; called by muse, mutect2, varscan2
- ESYT3 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100004888, COSV56681869; called by muse, mutect2, varscan2
- EWSR1 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV100131848; called by muse, mutect2, varscan2
- F7 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM041344, CM0911461, COSV100661059; called by muse, mutect2, varscan2
- F9 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99496727; called by muse, mutect2, varscan2
- FAM155A | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101029249, COSV65550070; called by muse, mutect2, varscan2
- FAM161A | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101295708; called by muse, mutect2, varscan2
- FAP | c.2222C>A p.T741K | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51866042; called by muse, mutect2, varscan2
- FAT3 | c.5434G>C p.V1812L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99968058; called by muse, mutect2, varscan2
- FBN2 | c.3842G>A p.C1281Y | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99329094; called by muse, mutect2, varscan2
- FBN3 | c.739+1G>T p.X247_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99561397; called by muse, mutect2, varscan2
- FBN3 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99561401; called by muse, mutect2, varscan2
- FBXO10 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV99446961; called by muse, mutect2, varscan2
- FER1L5 | c.6204C>A p.D2068E (on ENST00000623019; = p.D2032E on NM_001293083.2) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs766088293, COSV99383496; called by muse, mutect2, varscan2
- FGA | c.2496C>G p.N832K | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100120549; called by muse, mutect2, varscan2
- FLRT2 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100420710; called by muse, mutect2, varscan2
- FLT3 | c.2461C>G p.H821D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99609567; called by muse, mutect2, varscan2
- FN3K | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100333334; called by muse, mutect2, varscan2
- FNDC3B | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 170/321 reads (53%) | catalogued as COSV100394533; called by muse, mutect2, varscan2
- FOXA2 | c.635C>T p.S212F (on ENST00000377115 / NM_153675.3; = p.S218F on NM_021784.5) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008418; called by muse, mutect2, varscan2
- FPGT | c.720C>G p.F240L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100907367; called by muse, mutect2, varscan2
- FREM2 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99749716; called by muse, mutect2, varscan2
- FRMPD1 | c.3938C>A p.A1313D | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100899594; called by muse, mutect2, varscan2
- FRMPD2 | c.3268G>T p.G1090* | Nonsense Mutation (SNP) | VAF 55/403 reads (14%) | catalogued as COSV100564004; called by muse, mutect2, varscan2
- FRMPD2 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100564005; called by muse, mutect2, varscan2
- GABBR2 | c.1225T>C p.F409L | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV99410750; called by muse, mutect2, varscan2
- GALNT17 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100354817; called by muse, mutect2, varscan2
- GALNTL5 | c.1081A>G p.I361V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV101217877; called by muse, mutect2, varscan2
- GALNTL6 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV101560350; called by muse, mutect2, varscan2
- GFRA2 | c.1052C>G p.A351G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100151898; called by muse, mutect2, varscan2
- GJA5 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99605696; called by muse, mutect2, varscan2
- GLI2 | c.4306A>G p.M1436V (on ENST00000361492 / NM_001374353.1; = p.M1453V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as COSV100083747, COSV58039558; called by muse, mutect2, varscan2
- GLT1D1 | c.802del p.V268Yfs*13 (on ENST00000442111 / NM_001366889.1; = p.V188Yfs*13 on NM_144669.3) | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as COSV99895912; called by mutect2, pindel, varscan2
- GLUL | c.604-2A>G p.X202_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100092112; called by muse, mutect2, varscan2
- GP2 | c.1451G>T p.S484I (on ENST00000381362 / NM_001007240.3; = p.S481I on NM_001502.4) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV100221570; called by muse, mutect2, varscan2
- GP9 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100264691; called by muse, mutect2, varscan2
- GPR101 | c.1412A>T p.K471M | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV99981529; called by muse, mutect2, varscan2
- GPR27 | c.929T>A p.V310E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV99816557; called by muse, mutect2, varscan2
- GREB1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99303347; called by muse, mutect2
- GRHL2 | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.092); catalogued as rs867249108, COSV99307431; called by muse, varscan2
- GRID2 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56225042; called by muse, mutect2, varscan2
- GRIN2A | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100410472; called by muse, mutect2, varscan2
- GRM3 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs765170035, COSV64479201; called by muse, varscan2
- GSC | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 39/148 reads (26%) | catalogued as COSV99450267; called by muse, mutect2, varscan2
- GSC | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV99450272; called by muse, mutect2, varscan2
- GSS | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99404517; called by muse, mutect2, varscan2
- GTF2E1 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV52206770, COSV99382054; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1956G>T p.M652I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99735041; called by muse, mutect2, varscan2
- GTSE1 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV101483230; called by muse, mutect2, varscan2
- GUCY1B1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV100025751; called by muse, mutect2, varscan2
- GXYLT2 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV101274642; called by muse, mutect2, varscan2
- GYPA | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.847); catalogued as COSV99302335; called by muse, mutect2, varscan2
- GYPB | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.385); catalogued as rs1355474673, COSV99301863, COSV99302330; called by muse, mutect2, varscan2
- HDC | c.1462G>T p.G488W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1433567246, COSV51068626, COSV99984190; called by muse, mutect2, varscan2
- HECTD4 | c.5924G>C p.R1975P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101108018; called by muse, mutect2
- HELZ | c.3619G>A p.V1207M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.038); catalogued as COSV100698908; called by muse, mutect2, varscan2
- HELZ | c.1866G>A p.M622I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100698910; called by muse, mutect2, varscan2
- HERC5 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99987960; called by muse, mutect2, varscan2
- HERPUD2 | c.1059+2T>C p.X353_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100258036; called by muse, mutect2, varscan2
- HNRNPU | c.1990G>C p.G664R (on ENST00000283179; = p.G726R on NM_004501.3) | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); catalogued as rs762632266, COSV99310477; called by muse, mutect2, varscan2
- HOXA7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99636596; called by muse, mutect2, varscan2
- HRNR | c.2026G>A p.G676S | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as rs141565920; called by muse, mutect2, varscan2
- HSD3B2 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as COSV101027525; called by muse, mutect2, varscan2
- HSPA13 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV99580173; called by muse, mutect2, varscan2
- HSPA1A | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100989356; called by muse, mutect2, varscan2
- HTR1E | c.530A>T p.H177L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV100541192; called by muse, mutect2, varscan2
- HTR3E | c.671C>A p.T224N (on ENST00000415389 / NM_001256613.1; = p.T239N on NM_182589.2) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100094300; called by muse, mutect2, varscan2
- HTRA1 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934775; called by muse, mutect2, varscan2
- IDH1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61615881; called by muse, mutect2, varscan2
- IFI44L | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 71/108 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV100655039; called by muse, mutect2, varscan2
- IGHD | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs1175016669, COSV101162971; called by muse, mutect2
- IGKV3-11 | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs753050711; called by muse, mutect2, varscan2
- IGSF3 | c.1846C>G p.R616G (on ENST00000369486 / NM_001007237.3; = p.R636G on NM_001542.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100604932; called by muse, mutect2, varscan2
- IKBIP | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100689858; called by muse, mutect2, varscan2
- IL12B | c.75A>C p.E25D | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99180362; called by muse, mutect2, varscan2
- IL13 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100449426; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1858C>G p.R620G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as COSV100147047, COSV100148571, COSV56290459; called by muse, mutect2, varscan2
- INHBC | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100548033; called by muse, mutect2, varscan2
- INPP4A | c.1895C>T p.P632L (on ENST00000074304 / NM_001134224.1; = p.P593L on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1394330959, COSV99303383, COSV99304207; called by muse, mutect2, varscan2
- INPP4B | c.2672A>G p.K891R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99525574; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1000G>A p.E334K (on ENST00000485419 / NM_001197113.1; = p.E258K on NM_014575.3) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100541483; called by muse, mutect2, varscan2
- IRX6 | c.154T>A p.Y52N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99306648; called by muse, mutect2, varscan2
- ITGA11 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100241907; called by muse, mutect2, varscan2
- ITPRID1 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as rs1487895278, COSV100086988; called by muse, mutect2, varscan2
- IZUMO2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.201); catalogued as rs960962806, COSV99518330; called by muse, mutect2, varscan2
- JAKMIP1 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51528613, COSV99290214; called by muse, mutect2, varscan2
- JARID2 | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100522084; called by muse, mutect2, varscan2
- KALRN | c.6080G>T p.R2027L (on ENST00000360013 / NM_001024660.4; = p.R330L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as COSV99362502; called by muse, mutect2, varscan2
- KAT6B | c.4414G>T p.E1472* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99768558; called by muse, mutect2, varscan2
- KBTBD3 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV101595707; called by muse, mutect2, varscan2
- KCNA4 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs753892596, COSV60251560; called by muse, mutect2, varscan2
- KCNIP1 | c.227C>A p.P76H (on ENST00000411494 / NM_001034837.3; = p.P65H on NM_014592.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100198721; called by muse, mutect2, varscan2
- KCNK18 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV100572090; called by muse, mutect2, varscan2
- KCNMA1 | c.2285C>G p.S762* (on ENST00000286628 / NM_001161352.2; = p.S704* on NM_002247.4) | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV99697695, COSV99698594; called by muse, mutect2, varscan2
- KCNV1 | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV52088664; called by muse, mutect2, varscan2
- KDM4B | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99030969; called by muse, mutect2, varscan2
- KDM4C | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV101185002; called by muse, mutect2, varscan2
- KDM5D | c.3386A>T p.D1129V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100522278; called by muse, mutect2, varscan2
- KHDRBS2 | c.1024A>G p.R342G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764718218, COSV99835619; called by muse, mutect2, varscan2
- KIF25 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV100596423; called by muse, mutect2, varscan2
- KIF4B | c.1178A>T p.Q393L | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV101469355; called by muse, mutect2, varscan2
- KIFAP3 | c.1898-1G>C p.X633_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100847027; called by muse, mutect2
- KIT | c.2262del p.A755Pfs*10 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | catalogued as COSV55398698, COSV99855727; called by mutect2, pindel, varscan2
- KIT | c.2918A>G p.H973R | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV99854855; called by muse, mutect2, varscan2
- KLB | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99962328; called by muse, mutect2, varscan2
- KMT2A | c.3173C>A p.S1058* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV100629321, COSV100630215, COSV63292308; called by muse, mutect2, varscan2
- KMT2D | c.5146G>T p.A1716S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.609); catalogued as COSV56408019; called by muse, mutect2, varscan2
- KMT2D | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV56407319, COSV56493934; called by muse, mutect2, varscan2
- KPTN | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.035); catalogued as COSV99370178; called by muse, mutect2, varscan2
- KRT12 | c.1218G>T p.E406D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52430682; called by muse, mutect2, varscan2
- KRT18 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs148580152; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT25 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100379997; called by muse, mutect2, varscan2
- KRT33B | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99290713; called by muse, mutect2, varscan2
- KRT34 | c.1038G>T p.E346D | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101222685; called by muse, varscan2
- KRT78 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.091); catalogued as rs1353595997, COSV58851908; called by muse, mutect2, varscan2
- KRTAP1-3 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV100727478; called by muse, mutect2, varscan2
- KRTAP13-3 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as rs746858252, COSV100481777; called by muse, mutect2, varscan2
- KYAT3 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99556620; called by muse, mutect2, varscan2
- LAMA1 | c.2422C>T p.L808F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV101057016; called by muse, mutect2, varscan2
- LARP4 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99529444; called by muse, mutect2, varscan2
- LBP | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs1385118406, COSV54145228; called by muse, mutect2, varscan2
- LEF1 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99489839; called by muse, mutect2, varscan2
- LILRA4 | c.1132G>T p.A378S | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99393255; called by muse, varscan2
- LILRB1 | c.1717C>A p.P573T (on ENST00000427581; = p.P523T on NM_006669.6) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100207561; called by muse, mutect2, varscan2
- LITAF | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100243185; called by muse, mutect2, varscan2
- LIX1L | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100811075; called by muse, mutect2, varscan2
- LLGL2 | c.2668A>G p.I890V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV99390119; called by muse, mutect2, varscan2
- LMLN | c.1334A>T p.K445M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100218732; called by muse, mutect2, varscan2
- LRAT | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100312134, COSV60476467; called by muse, mutect2, varscan2
- LRFN5 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV99984684; called by muse, mutect2, varscan2
- LRRC66 | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV58633213; called by muse, mutect2, varscan2
- LRRC7 | c.1873G>A p.V625M (on ENST00000651989 / NM_001370785.2; = p.V592M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs759293934, COSV99228248; called by muse, mutect2, varscan2
- LRRK2 | c.1366C>A p.P456T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100109932, COSV100110781; called by muse, mutect2, varscan2
- LRRK2 | c.3165G>C p.L1055F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100110782; called by muse, mutect2, varscan2
- LRRTM4 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69141022; called by muse, mutect2, varscan2
- LRSAM1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100031714; called by muse, mutect2, varscan2
- LSM11 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99643995; called by muse, mutect2, varscan2
- LTBP2 | c.4838A>T p.D1613V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.776); catalogued as COSV100000682; called by muse, mutect2, varscan2
- LVRN | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV100773576; called by muse, mutect2, varscan2
- LYZL2 | c.209G>C p.R70P (on ENST00000375318; = p.R24P on NM_183058.3) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375255325, COSV100940618; called by muse, mutect2, varscan2
- MACF1 | c.2428A>T p.K810* | Nonsense Mutation (SNP) | VAF 47/76 reads (62%) | catalogued as COSV100485471; called by muse, mutect2, varscan2
- MAGEA3 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.26); catalogued as COSV100939068; called by muse, mutect2, varscan2
- MAGEA4 | c.850T>A p.Y284N | Missense Mutation (SNP) | VAF 91/153 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99367621; called by muse, mutect2, varscan2
- MASP2 | c.1288T>A p.C430S | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101280315; called by muse, mutect2, varscan2
- MC5R | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1187889128, COSV100229109; called by muse, mutect2, varscan2
- MCF2L2 | c.2713-1G>T p.X905_splice | Splice Site (SNP) | VAF 26/163 reads (16%) | catalogued as COSV100193298; called by muse, mutect2, varscan2
- MCTP1 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387682, COSV56517896; called by muse, mutect2, varscan2
- MECOM | c.2992C>A p.Q998K (on ENST00000468789 / NM_001105078.4; = p.Q1186K on NM_004991.4) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99245012; called by muse, mutect2, varscan2
- MEIS1 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.41); catalogued as COSV99715489; called by muse, mutect2, varscan2
- MESP2 | c.848C>G p.S283W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100510799; called by muse, mutect2, varscan2
- METTL1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.123); catalogued as COSV99141605; called by muse, mutect2, varscan2
- MFHAS1 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99359756; called by muse, mutect2, varscan2
- MFSD9 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV99302219; called by muse, mutect2, varscan2
- MMP20 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1365129422, COSV99497811; called by muse, mutect2, varscan2
- MPPED2 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV100813409; called by muse, mutect2, varscan2
- MROH9 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371741888, COSV100882689, COSV100882717; called by muse, mutect2, varscan2
- MSI2 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs778326895, COSV52362965; called by muse, mutect2, varscan2
- MTDH | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100292675; called by muse, mutect2, varscan2
- MUC16 | c.38095G>T p.V12699L | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV101198350, COSV101200505; called by muse, mutect2, varscan2
- MUC16 | c.28160C>T p.S9387L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV101200506; called by muse, mutect2, varscan2
- MUC16 | c.27788C>G p.T9263R | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as rs190782019, COSV101200507; called by muse, mutect2, varscan2
- MUC16 | c.11552A>T p.Q3851L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as COSV101200509; called by muse, mutect2, varscan2
- MYH15 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99843835; called by muse, mutect2, varscan2
- MYH2 | c.5698G>A p.A1900T | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99820553; called by muse, mutect2, varscan2
- MYH2 | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1049022189, COSV55434777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.2954C>A p.T985K | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99820557; called by muse, mutect2, varscan2
- MYH4 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770067160, COSV55111784; called by muse, mutect2, varscan2
- MYH8 | c.3424C>T p.L1142F | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV101238512, COSV67972815; called by muse, mutect2, varscan2
- MYO1C | c.494A>C p.E165A (on ENST00000648651 / NM_001080779.2; = p.E130A on NM_033375.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV100704469; called by muse, varscan2
- MYO1F | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.482); catalogued as COSV100596884; called by muse, mutect2, varscan2
- MYOCD | c.253+1G>T p.X85_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100591069; called by muse, mutect2, varscan2
- MYT1 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100115074; called by muse, mutect2, varscan2
- MYT1L | c.2697A>T p.Q899H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101221048; called by muse, mutect2, varscan2
- NAALADL2 | c.1352A>G p.H451R | Missense Mutation (SNP) | VAF 71/413 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101380339; called by muse, mutect2, varscan2
- NAV2 | c.3500G>T p.S1167I (on ENST00000396087 / NM_001244963.2; = p.S1144I on NM_145117.5) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100217338; called by muse, mutect2, varscan2
- NBAS | c.4227G>T p.W1409C | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV99870818; called by muse, mutect2, varscan2
- NCAPH | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53635783, COSV99545996; called by muse, mutect2, varscan2
- NCKAP5 | c.4120C>G p.P1374A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV100493369; called by muse, mutect2, varscan2
- NCKAP5L | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100258999; called by muse, mutect2, varscan2
- NCR1 | c.42T>A p.C14* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99401055; called by muse, mutect2, varscan2
- NCR2 | c.376T>G p.Y126D | Missense Mutation (SNP) | VAF 65/97 reads (67%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.654); catalogued as COSV100897244; called by muse, mutect2, varscan2
- NDNF | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as COSV101113217; called by muse, mutect2, varscan2
- NECAB1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV101341132; called by muse, mutect2, varscan2
- NEMF | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV100027831; called by muse, mutect2, varscan2
- NES | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100957931; called by muse, mutect2, varscan2
- NETO1 | c.1523A>T p.H508L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100199194; called by muse, mutect2, varscan2
- NIN | c.113A>C p.H38P | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99814286; called by muse, mutect2, varscan2
- NKAPL | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100642525; called by muse, mutect2, varscan2
- NLRP4 | c.1859C>A p.S620* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100016726, COSV56718784; called by muse, mutect2, varscan2
- NME8 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99553582; called by muse, mutect2, varscan2
- NOL8 | c.2073A>G p.I691M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100694629; called by muse, mutect2, varscan2
- NOP14 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100054863; called by muse, mutect2, varscan2
- NOTCH4 | c.3892G>A p.A1298T | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100900815; called by muse, mutect2, varscan2
- NR0B1 | c.1133A>C p.Y378S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100973554, COSV100973597; called by muse, mutect2, varscan2
- NR1H4 | c.655T>C p.S219P (on ENST00000551379 / NM_001206993.2; = p.S205P on NM_005123.4) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500898; called by muse, mutect2, varscan2
- NRG3 | c.2033G>C p.S678T (on ENST00000404547 / NM_001370084.1; = p.S654T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.318); catalogued as COSV100932338; called by muse, mutect2, varscan2
- NRXN1 | c.1627A>G p.I543V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs771748547, COSV100456052; called by muse, varscan2
- NRXN1 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101278019; called by muse, varscan2
- NSD1 | c.2167A>T p.T723S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV100729617; called by muse, mutect2, varscan2
- NSUN5 | c.1144A>T p.R382W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99392479; called by muse, mutect2, varscan2
- NUP214 | c.1847C>A p.S616Y | Missense Mutation (SNP) | VAF 245/582 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as COSV100845349; called by muse, mutect2, varscan2
- NXPE1 | c.596G>A p.G199D (on ENST00000424269; = p.G57D on NM_152315.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV99320710; called by muse, mutect2, varscan2
- OBSCN | c.11000G>T p.G3667V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99481810; called by muse, mutect2, varscan2
- OPA3 | c.437A>T p.Q146L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99619958; called by muse, mutect2, varscan2
- OR11H6 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100209889; called by muse, mutect2, varscan2
- OR13G1 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV62943389; called by muse, mutect2, varscan2
- OR14A16 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100713812, COSV62926244; called by muse, mutect2, varscan2
- OR1L6 | c.425T>C p.M142T (on ENST00000373684; = p.M106T on NM_001004453.2) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs761369218, COSV100490952; called by muse, mutect2, varscan2
- OR1S2 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs768817083, COSV100224284; called by muse, mutect2, varscan2
- OR2A14 | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV101376480; called by muse, mutect2, varscan2
- OR2AK2 | c.439T>A p.C147S | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100824095; called by muse, mutect2, varscan2
- OR2C3 | c.294T>A p.C98* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100825741; called by muse, mutect2, varscan2
- OR2F1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101231317; called by muse, mutect2, varscan2
- OR2J3 | c.663T>A p.Y221* | Nonsense Mutation (SNP) | VAF 16/163 reads (10%) | catalogued as COSV101013643, COSV101013662; called by muse, mutect2, varscan2
- OR2M3 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 150/626 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101513478; called by muse, mutect2, varscan2
- OR2M3 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 173/425 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101513479, COSV71759094; called by muse, mutect2, varscan2
- OR2M5 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 38/92 reads (41%) | catalogued as COSV100822845, COSV63546104; called by muse, mutect2, varscan2
- OR2T11 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV100424893; called by muse, mutect2, varscan2
- OR2T12 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV58775882; called by muse, mutect2, varscan2
- OR4A16 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as rs774499821, COSV100125326; called by muse, mutect2, varscan2
- OR4C6 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.16); catalogued as COSV100051722, COSV100051927; called by muse, mutect2, varscan2
- OR4C6 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100051526, COSV100051727; called by muse, mutect2, varscan2
- OR4D9 | c.513del p.N172Mfs*27 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as COSV61434374; called by mutect2, pindel, varscan2
- OR4F6 | c.522A>T p.L174F | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.33); catalogued as COSV100186955; called by muse, mutect2, varscan2
- OR4K13 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- OR4K2 | c.829A>T p.I277F | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100064593; called by muse, mutect2, varscan2
- OR4M1 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 70/641 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100271349, COSV60061502; called by muse, mutect2, varscan2
- OR4Q3 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100057209, COSV100057282; called by muse, mutect2, varscan2
- OR4S2 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100412727; called by muse, mutect2, varscan2
- OR51Q1 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100333019; called by muse, mutect2, varscan2
- OR51V1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs151191536; called by muse, mutect2, varscan2
- OR56B1 | c.332A>G p.Y111C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1198524408, COSV100402668; called by muse, mutect2, varscan2
- OR5D16 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV65721541; called by muse, mutect2, varscan2
- OR5D16 | c.809G>T p.R270M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs939135809, COSV101004060; called by muse, mutect2, varscan2
- OR5H14 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 98/564 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV71193544; called by muse, mutect2, varscan2
- OR5J2 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV100399146; called by muse, mutect2, varscan2
- OR5M1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101591577; called by muse, varscan2
- OR5M1 | c.493C>G p.H165D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as COSV101591578, COSV73202149; called by muse, mutect2, varscan2
- OR5M3 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100392599; called by muse, mutect2, varscan2
- OR5T2 | c.718T>A p.Y240N | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV100506999; called by muse, mutect2, varscan2
- OR6K6 | c.219G>T p.M73I (on ENST00000368144; = p.M49I on NM_001005184.1) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933761, COSV63743622; called by muse, mutect2, varscan2
- OR6Q1 | c.744C>A p.H248Q | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110246, COSV56933478; called by muse, mutect2, varscan2
- OR6S1 | c.103C>A p.L35I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV100289446; called by muse, mutect2, varscan2
- OR6X1 | c.582A>T p.E194D | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100020604; called by muse, mutect2, varscan2
- OR8B3 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1408416821, COSV100660421; called by muse, mutect2, varscan2
- OR8H3 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); catalogued as COSV100539085; called by muse, mutect2, varscan2
- OR8H3 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100539087, COSV57908363; called by muse, mutect2, varscan2
- OR8K3 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100449830; called by muse, mutect2
- ORC4 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99932366; called by muse, mutect2, varscan2
- ORM2 | c.189A>T p.Q63H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV99407620; called by muse, mutect2, varscan2
- OTOP1 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs770481456, COSV99587887; called by muse, mutect2, varscan2
- PACS1 | c.2208-1G>A p.X736_splice | Splice Site (SNP) | VAF 40/166 reads (24%) | catalogued as COSV100270314; called by muse, mutect2, varscan2
- PALM | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99214636; called by muse, mutect2, varscan2
- PARD3 | c.1469T>A p.V490E | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100401484; called by muse, mutect2, varscan2
- PARP12 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as COSV99694190; called by muse, mutect2, varscan2
- PASD1 | c.1760T>A p.L587Q | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64854022; called by muse, mutect2, varscan2
- PAX5 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100814428; called by muse, mutect2, varscan2
- PCDH15 | c.4628C>A p.T1543K | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs761946902, COSV100905148; called by muse, mutect2, varscan2
- PCDH15 | c.475-1G>T p.X159_splice | Splice Site (SNP) | VAF 40/136 reads (29%) | catalogued as COSV100219125, COSV57354800; called by muse, mutect2, varscan2
- PCDH17 | c.1594G>T p.G532W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100931783, COSV64973397; called by muse, mutect2, varscan2
- PCDH17 | c.1860C>A p.S620R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100931786, COSV64976441; called by muse, mutect2, varscan2
- PCDHA1 | c.1973C>G p.A658G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as rs564427730, COSV100974403, COSV65372688, COSV65377461; called by muse, varscan2
- PCDHA12 | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 67/265 reads (25%) | catalogued as COSV100252215; called by muse, varscan2
- PCDHA12 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs1174243985, COSV100252217; called by muse, varscan2
- PCDHA3 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV63545732; called by muse, varscan2
- PCDHAC2 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99151267; called by muse, mutect2, varscan2
- PCDHB14 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99506103; called by muse, mutect2, varscan2
- PCDHB15 | c.713A>T p.N238I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99179041; called by muse, mutect2, varscan2
- PCDHB16 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99502449; called by muse, mutect2, varscan2
- PCDHB2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99522789, COSV99523365; called by muse, mutect2, varscan2
- PCF11 | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100018820; called by muse, mutect2, varscan2
- PCMT1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100953493; called by muse, mutect2, varscan2
- PCNT | c.8521G>T p.A2841S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV100855761; called by muse, mutect2, varscan2
- PCNX1 | c.5440A>T p.N1814Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99456487; called by muse, mutect2, varscan2
- PCSK2 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360164; called by muse, mutect2, varscan2
- PCSK6 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.575); catalogued as rs769260625, COSV100624188; called by muse, mutect2, varscan2
- PDCD4 | c.768A>T p.R256S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV99701079; called by muse, mutect2, varscan2
- PDE1C | c.751-1G>C p.X251_splice | Splice Site (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100373115; called by muse, mutect2, varscan2
- PDE1C | c.461G>C p.S154T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.321); catalogued as COSV100373118; called by muse, mutect2
- PDGFRA | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV57268817, COSV57271168, COSV99957163; called by muse, mutect2, varscan2
- PDILT | c.1637C>G p.S546C | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as COSV100199637; called by muse, mutect2, varscan2
- PDZRN3 | c.1839G>T p.L613F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99728360; called by muse, mutect2, varscan2
- PEBP4 | c.261C>A p.G87= | Splice Region (SNP) | VAF 30/91 reads (33%) | catalogued as COSV99835206; called by muse, mutect2, varscan2
- PEG3 | c.431T>A p.M144K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV99689658; called by muse, mutect2, varscan2
- PGAP6 | c.2197G>C p.A733P | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99170736; called by muse, mutect2, varscan2
- PHACTR3 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs767039366, COSV100732868; called by muse, mutect2, varscan2
- PHRF1 | c.3542G>T p.R1181L (on ENST00000264555 / NM_001286581.2; = p.R1180L on NM_020901.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs761451455, COSV52751616; called by muse, mutect2, varscan2
- PINK1 | c.1667T>A p.M556K | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100387361; called by muse, mutect2, varscan2
- PIP5K1C | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM073263, COSV100095749, COSV58955954; called by muse, mutect2, varscan2
- PIWIL1 | c.608C>A p.P203H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99806683; called by muse, mutect2, varscan2
- PKD1 | c.6091G>T p.V2031L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as COSV99238576; called by muse, mutect2, varscan2
- PKD1 | c.1386-2A>G p.X462_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99238578; called by muse, mutect2, varscan2
- PKHD1 | c.7207G>T p.G2403C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378157664, COSV100583817; called by muse, mutect2, varscan2
- PKHD1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 180/324 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs374447352, COSV100583818; called by muse, mutect2, varscan2
- PLA2G4F | c.857A>C p.E286A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV101215262; called by muse, mutect2, varscan2
- PLCB3 | c.388-2A>T p.X130_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99657593; called by muse, mutect2, varscan2
- PLCG2 | c.3544G>C p.V1182L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759887275, COSV100842467; called by muse, mutect2, varscan2
- PLCL1 | c.2309A>T p.Q770L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV70840697; called by muse, mutect2, varscan2
- PLPPR3 | c.657+7C>A | Splice Region (SNP) | VAF 25/51 reads (49%) | catalogued as COSV100608882; called by muse, mutect2, varscan2
- PLPPR5 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99587610; called by muse, mutect2, varscan2
- PLSCR4 | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100724279; called by muse, mutect2, varscan2
- PNRC1 | c.281C>G p.P94R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.049); catalogued as COSV100259976; called by muse, mutect2
- POLE | c.3332G>A p.R1111Q | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs114315196, COSV57681369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.63-2A>T p.X21_splice | Splice Site (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100267527; called by muse, mutect2, varscan2
- POU1F1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100622730; called by muse, mutect2, varscan2
- POU4F3 | c.838T>A p.S280T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100047149; called by muse, mutect2, varscan2
- PPP2R2B | c.1148A>T p.K383M (on ENST00000394409; = p.K449M on NM_181674.2) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV100355544; called by muse, mutect2, varscan2
- PPP4R4 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100428823; called by muse, mutect2, varscan2
- PRAG1 | c.2614C>T p.H872Y | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV100422470; called by muse, mutect2, varscan2
- PRDM16 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99577773; called by muse, varscan2
- PREX2 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV99908566; called by muse, mutect2
- PRIMA1 | c.412A>C p.S138R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100301362; called by muse, mutect2, varscan2
- PRKAB1 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV99982431; called by muse, mutect2, varscan2
- PRKCG | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV99669293; called by muse, mutect2, varscan2
- PRKDC | c.8138A>G p.D2713G | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100041651; called by muse, mutect2, varscan2
- PRR30 | c.892T>A p.F298I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99574658; called by muse, mutect2, varscan2
- PRR5 | c.812C>A p.A271E (on ENST00000336985 / NM_181333.4; = p.A262E on NM_015366.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV50059577, COSV99134631; called by muse, mutect2, varscan2
- PRRC2B | c.2753G>T p.W918L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100621987; called by muse, mutect2, varscan2
- PSG11 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100105986; called by muse, mutect2, varscan2
- PSG2 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs774584260, COSV101290493; called by muse, mutect2, varscan2
- PTCD3 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99606487; called by muse, mutect2, varscan2
- PTCRA | c.265T>G p.L89V | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.235); catalogued as COSV100485796; called by muse, mutect2, varscan2
- PTGER2 | c.326G>C p.C109S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55418227, COSV55419785, COSV99817585; called by muse, mutect2, varscan2
- PTGS1 | c.1728C>A p.Y576* | Nonsense Mutation (SNP) | VAF 32/137 reads (23%) | catalogued as COSV99793358, COSV99793363; called by muse, mutect2, varscan2
- PTH2R | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774742460, COSV55917376, COSV99782702; called by muse, mutect2, varscan2
- PTK2B | c.1520A>G p.Y507C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs775132770, COSV100594214; called by muse, mutect2
- PTPDC1 | c.778G>T p.A260S (on ENST00000375360 / NM_177995.3; = p.A312S on NM_152422.4) | Missense Mutation (SNP) | VAF 133/213 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.174); catalogued as COSV56626849, COSV99997776; called by muse, mutect2, varscan2
- PTPN22 | c.1958C>A p.S653* (on ENST00000359785 / NM_001193431.2; = p.S598* on NM_012411.5) | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV100703801; called by muse, mutect2, varscan2
- PTPRC | c.3356A>T p.Q1119L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100722847; called by muse, varscan2
- PTPRD | c.3808G>C p.V1270L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100645710; called by muse, mutect2, varscan2
- PTPRM | c.3656G>T p.C1219F | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); catalogued as COSV100158867; called by muse, mutect2, varscan2
- PTPRN2 | c.2792A>G p.N931S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV66104703; called by muse, mutect2, varscan2
- PTPRR | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99318190; called by muse, mutect2, varscan2
- PTPRT | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100628930; called by muse, mutect2, varscan2
- PXDN | c.1858G>T p.G620* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99414239; called by muse, mutect2, varscan2
- PYGL | c.1471C>A p.R491S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM078412, COSV99368859, COSV99369196; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV50251254, COSV99242277; called by muse, mutect2, varscan2
- RAB7A | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV99414190; called by muse, mutect2, varscan2
- RANBP3L | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV99683933; called by muse, mutect2
- RASA4 | c.381G>C p.W127C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs760296778, COSV53551186; called by muse, mutect2, varscan2
- RBFOX1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100302535; called by muse, mutect2, varscan2
- RELN | c.1803G>C p.W601C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634258; called by muse, mutect2, varscan2
- RET | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV100394055; called by muse, mutect2, varscan2
- RETREG3 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.231); catalogued as COSV99519011; called by muse, mutect2, varscan2
- RFTN1 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.668); catalogued as COSV100489627; called by muse, mutect2, varscan2
- RFX1 | c.328A>C p.M110L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV99586267; called by muse, mutect2
- RGS3 | c.3059G>T p.R1020L (on ENST00000350696 / NM_001282923.2; = p.R739L on NM_130795.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100636856, COSV59512769; called by muse, mutect2, varscan2
- RGS9 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV99287732; called by muse, mutect2, varscan2
- RHAG | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100006714; called by muse, mutect2, varscan2
- RIMKLB | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100223991; called by muse, mutect2, varscan2
- RIMS2 | c.1324C>G p.P442A (on ENST00000666250 / NM_001348490.2; = p.P250A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV99177415; called by muse, mutect2, varscan2
- RIMS2 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.06); catalogued as COSV99177442; called by muse, mutect2, varscan2
- RIN3 | c.1272C>G p.D424E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.07); catalogued as COSV99379615; called by muse, mutect2, varscan2
- RINT1 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs748446895, COSV99994504; called by muse, mutect2, varscan2
- RINT1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs770101080, COSV57557811; called by muse, mutect2, varscan2
- RNF17 | c.2471G>T p.C824F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99693830; called by muse, mutect2
- ROBO2 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV101533703; called by muse, mutect2
- ROBO4 | c.2715C>G p.H905Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100127734; called by muse, mutect2, varscan2
- ROCK1 | c.1985C>T p.S662L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101296316, COSV67698905; called by muse, varscan2
- RORB | c.1136T>A p.I379K (on ENST00000396204 / NM_001365023.1; = p.I368K on NM_006914.4) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100974399; called by muse, mutect2, varscan2
- RP1L1 | c.1570A>T p.R524W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV101223430; called by muse, mutect2, varscan2
- RPH3A | c.671C>A p.P224H (on ENST00000389385 / NM_001143854.2; = p.P220H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV101231854; called by muse, mutect2, varscan2
- RPH3A | c.1387C>T p.L463F (on ENST00000389385 / NM_001143854.2; = p.L459F on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941902023, COSV101231855; called by muse, mutect2, varscan2
- RPL23 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV99834750, COSV99834800; called by muse, mutect2, varscan2
- RTN4IP1 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | catalogued as rs755175825, COSV100954206; called by muse, mutect2, varscan2
- RUNDC1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV100799374; called by muse, mutect2, varscan2
- RXRG | c.1138+1G>T p.X380_splice | Splice Site (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100717716; called by muse, mutect2, varscan2
- RXRG | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100717718; called by muse, mutect2, varscan2
- RYR2 | c.12179A>C p.Q4060P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100771937; called by muse, mutect2, varscan2
- RYR3 | c.8045G>A p.G2682D (on ENST00000389232; = p.G2683D on NM_001036.6) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV101213235; called by muse, mutect2, varscan2
- SAMD3 | c.269+1G>A p.X90_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as rs1282196981, COSV100148324; called by muse, mutect2, varscan2
- SAMD3 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs755821130, COSV100148326; called by muse, mutect2, varscan2
- SAMSN1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53475078, COSV99581958; called by muse, mutect2, varscan2
- SART3 | c.1364-1G>T p.X455_splice (on ENST00000228284; = p.X437_splice on NM_014706.4) | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99934252; called by muse, mutect2, varscan2
- SBNO1 | c.4069C>T p.P1357S (on ENST00000420886; = p.P1356S on NM_018183.5) | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99929450; called by muse, mutect2, varscan2
- SCAF4 | c.1615A>G p.M539V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs199548875, COSV99741802; called by muse, mutect2, varscan2
- SCN10A | c.3448G>T p.E1150* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV101479470; called by muse, mutect2, varscan2
- SCN11A | c.1595C>A p.T532N | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.425); catalogued as COSV100181997; called by muse, mutect2, varscan2
- SCN3A | c.770G>T p.C257F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99327676; called by muse, mutect2, varscan2
- SEC16A | c.5365G>C p.A1789P | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99255617, COSV99259384; called by muse, mutect2, varscan2
- SEMA5B | c.1224C>A p.N408K | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as rs758914141, COSV99532537; called by muse, mutect2, varscan2
- SEPTIN4 | c.1606+7G>T | Splice Region (SNP) | VAF 48/151 reads (32%) | catalogued as COSV100400398; called by muse, mutect2, varscan2
- SERAC1 | c.355+1G>C p.X119_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100894865; called by muse, mutect2, varscan2
- SERINC5 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101549110; called by muse, mutect2, varscan2
- SERPINA4 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100097340; called by muse, mutect2, varscan2
- SERPINA5 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 150/509 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV61575312; called by muse, mutect2, varscan2
- SFI1 | c.531A>T p.R177S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV101192175; called by muse, mutect2, varscan2
- SFRP4 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101460909; called by muse, mutect2, varscan2
- SGCZ | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as rs772544113, COSV101170775, COSV66033304; called by muse, mutect2, varscan2
- SGPP1 | c.1170A>T p.L390F | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as COSV99905921; called by muse, mutect2, varscan2
- SHOX | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100479166; called by muse, mutect2, varscan2
- SI | c.2948A>T p.Y983F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016387; called by muse, mutect2, varscan2
- SIM1 | c.1877A>T p.N626I | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.179); catalogued as COSV99492549; called by muse, mutect2, varscan2
- SLC12A1 | c.2519C>A p.A840E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101119008, COSV66794489; called by muse, mutect2, varscan2
- SLC14A2 | c.2414T>A p.F805Y | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.84); PolyPhen benign (0.043); catalogued as COSV99675811; called by muse, mutect2, varscan2
- SLC17A6 | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99581944; called by muse, mutect2, varscan2
- SLC18B1 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51593946, COSV99259242; called by muse, mutect2, varscan2
- SLC30A9 | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100048394; called by muse, mutect2, varscan2
- SLC35F4 | c.479T>C p.M160T (on ENST00000339762 / NM_001352015.2; = p.M124T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773946280, COSV100334038; called by muse, mutect2, varscan2
- SLC38A9 | c.1059A>G p.P353= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100591513; called by muse, mutect2, varscan2
- SLC6A15 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99881211; called by muse, mutect2, varscan2
- SLC6A5 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV100117036, COSV54228283; called by muse, mutect2, varscan2
- SLC8A1 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100246831; called by muse, mutect2, varscan2
- SLC9A9 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100341840; called by mutect2, varscan2
- SLCO1B1 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 42/145 reads (29%) | catalogued as COSV99918801; called by muse, mutect2, varscan2
- SLCO2A1 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100189149; called by muse, mutect2, varscan2
- SLCO2B1 | c.1613A>G p.N538S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV99214900; called by muse, mutect2, varscan2
- SLCO4C1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs768390707, COSV100195363; called by muse, mutect2, varscan2
- SLIT2 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56596477, COSV99885571; called by muse, mutect2, varscan2
- SMARCA4 | c.3928G>T p.E1310* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100759067, COSV60805272; called by muse, mutect2, varscan2
- SMPD4 | c.2420G>T p.R807M (on ENST00000409031 / NM_017951.4; = p.R778M on NM_017751.4) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1444804289, COSV60081669; called by muse, mutect2, varscan2
- SNX14 | c.2396G>T p.R799L (on ENST00000314673 / NM_001350535.1; = p.R746L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV100121674; called by muse, mutect2, varscan2
- SOGA3 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100846994, COSV64107755; called by muse, mutect2, varscan2
- SORBS2 | c.2932G>A p.G978S (on ENST00000284776 / NM_021069.5; = p.G544S on NM_003603.6) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748530727, COSV99511830; called by muse, mutect2, varscan2
- SPATA31D1 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs758771158, COSV100782918; called by muse, mutect2, varscan2
- SPATA31D1 | c.2948T>C p.L983P | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100782919; called by muse, mutect2, varscan2
- SPATA31D1 | c.3424G>T p.G1142C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as COSV100782920, COSV61193560; called by muse, mutect2, varscan2
- SPHKAP | c.3937T>G p.S1313A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100764278; called by muse, mutect2, varscan2
- SPN | c.842A>C p.Q281P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100788860; called by muse, mutect2, varscan2
- SPNS3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100337085; called by muse, mutect2, varscan2
- SPRR1B | c.150_173del p.H50_C57del | In Frame Del (DEL) | VAF 30/160 reads (19%) | catalogued as rs780959457; called by muse*, mutect2, varscan2*
- SPRY4 | c.860G>T p.S287I (on ENST00000434127 / NM_001127496.3; = p.S310I on NM_030964.4) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs377690087; called by muse, mutect2, varscan2
- SPTY2D1 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100311759, COSV60475239; called by muse, mutect2, varscan2
- SSTR3 | c.466A>T p.T156S | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100142759; called by muse, mutect2, varscan2
- SSTR4 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54799156; called by muse, mutect2, varscan2
- STK10 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99451912; called by muse, mutect2, varscan2
- STK3 | c.171A>T p.Q57H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV101372598; called by muse, mutect2, varscan2
- STX7 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100908490; called by muse, mutect2, varscan2
- STXBP5L | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs189688053, COSV99875300; called by muse, mutect2, varscan2
- STYXL2 | c.3221C>T p.S1074L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99609544; called by muse, mutect2, varscan2
- SULF1 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV52678287, COSV52678716, COSV99483703; called by muse, mutect2, varscan2
- SULT1C3 | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100227533; called by muse, mutect2, varscan2
- SUSD3 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs745843257, COSV100968902; called by muse, mutect2, varscan2
- SYCP1 | c.2638A>T p.K880* | Nonsense Mutation (SNP) | VAF 36/114 reads (32%) | catalogued as COSV101051037; called by muse, mutect2, varscan2
- SYNE1 | c.22664G>T p.R7555L (on ENST00000367255 / NM_182961.4; = p.R7484L on NM_033071.3) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99572239; called by muse, mutect2, varscan2
- SYNE1 | c.6792A>C p.L2264F (on ENST00000367255 / NM_182961.4; = p.L2271F on NM_033071.3) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1239985651, COSV99572243; called by muse, mutect2, varscan2
- SYNE1 | c.491C>T p.P164L (on ENST00000367255 / NM_182961.4; = p.P171L on NM_033071.3) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99572248; called by muse, mutect2, varscan2
- SYT3 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV58899254; called by muse, mutect2, varscan2
- SYTL2 | c.1898A>T p.Q633L (on ENST00000528231 / NM_001162951.2; = p.Q609L on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100314564; called by muse, mutect2, varscan2
- TAF5L | c.1232G>T p.W411L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99273456; called by muse, mutect2, varscan2
- TAL1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV53747329, COSV53748625; called by muse, mutect2, varscan2
- TAS1R2 | c.1490A>T p.K497M | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100946289; called by muse, mutect2, varscan2
- TAS2R38 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101516478, COSV71885666; called by muse, mutect2, varscan2
- TAS2R40 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV101283014; called by muse, mutect2, varscan2
- TBCD | c.2606C>T p.T869I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100833519; called by muse, mutect2, varscan2
- TBL1Y | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100667309; called by muse, mutect2, varscan2
- TBX22 | c.1290T>G p.S430R | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100960881; called by muse, mutect2, varscan2
- TBX6 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1008527309, COSV54223439; called by muse, mutect2, varscan2
- TBXT | c.1189G>T p.G397* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99752720; called by muse, mutect2, varscan2
- TCAIM | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV100703337; called by muse, mutect2, varscan2
- TDRD5 | c.2401C>T p.L801F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV54252000; called by muse, mutect2, varscan2
- TECRL | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs373269339, COSV101169172; called by muse, mutect2, varscan2
- TECTA | c.1846G>T p.D616Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50717891, COSV99880636; called by muse, mutect2, varscan2
- TENM1 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100950434; called by muse, mutect2, varscan2
- TESK1 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV99427547; called by muse, mutect2, varscan2
- TFR2 | c.1721T>A p.F574Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99774638; called by muse, mutect2, varscan2
- TG | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55078041, COSV99602088; called by muse, mutect2, varscan2
- TGFBR2 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV99847567; called by muse, mutect2, varscan2
- THBD | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101001908; called by muse, mutect2, varscan2
- THY1 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52454165; called by muse, mutect2, varscan2
- TIE1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV100992121, COSV65250371; called by muse, mutect2, varscan2
- TIMM44 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 36/149 reads (24%) | catalogued as COSV99564240; called by muse, mutect2, varscan2
- TINAG | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV99450183; called by muse, mutect2, varscan2
- TJP2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV99600851, COSV99601485; called by muse, mutect2, varscan2
- TKTL2 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV99761585; called by muse, mutect2, varscan2
- TLE2 | c.609G>C p.E203D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99504521; called by muse, mutect2, varscan2
- TLR7 | c.2755C>G p.P919A | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV101027990; called by muse, mutect2, varscan2
- TM2D2 | c.101A>G p.H34R | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as COSV101166179; called by muse, mutect2, varscan2
- TMBIM4 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748307919, COSV99660425; called by muse, mutect2, varscan2
- TMED6 | c.492C>T p.D164= | Splice Region (SNP) | VAF 33/64 reads (52%) | catalogued as rs938485307, COSV54741721; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs765130174, COSV99143371; called by muse, mutect2, varscan2
- TMEM131L | c.3412A>T p.N1138Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99547796; called by muse, mutect2, varscan2
- TMEM132D | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV101396252; called by muse, mutect2, varscan2
- TMEM252 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV101051137; called by muse, mutect2, varscan2
- TMEM270 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100260380; called by muse, mutect2, varscan2
- TMPRSS11F | c.1188T>A p.D396E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs754193530, COSV100678680; called by muse, mutect2, varscan2
- TNC | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 56/138 reads (41%) | catalogued as COSV100406034, COSV60780475; called by muse, varscan2
- TNFSF18 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.034); catalogued as COSV99514065; called by muse, mutect2, varscan2
- TNIK | c.4010C>A p.A1337E | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99458451; called by muse, mutect2, varscan2
- TNIK | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs376646276; called by muse, mutect2, varscan2
- TNKS | c.3037G>T p.G1013C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100127494; called by muse, mutect2, varscan2
- TNKS2 | c.1789C>A p.H597N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861130; called by muse, mutect2, varscan2
- TNN | c.1298A>G p.K433R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as COSV99512481; called by muse, mutect2, varscan2
- TNN | c.1867C>G p.P623A | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99512482; called by muse, varscan2
- TNS3 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 26/118 reads (22%) | catalogued as COSV100236014; called by muse, mutect2, varscan2
- TPO | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100221680; called by muse, mutect2, varscan2
- TRANK1 | c.1946C>A p.T649N | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV100083789; called by muse, mutect2, varscan2
- TRAT1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV99849386; called by muse, mutect2, varscan2
- TRAT1 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1163739042, COSV99849388; called by muse, mutect2, varscan2
- TRERF1 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 99/177 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.082); catalogued as COSV100551182; called by muse, mutect2, varscan2
- TRIM51 | c.1204G>T p.V402F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99792900; called by muse, mutect2, varscan2
- TRIML1 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs369748946; called by muse, mutect2, varscan2
- TRIML2 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100456199, COSV58716474; called by muse, mutect2, varscan2
- TRIO | c.7609G>T p.V2537L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.188); catalogued as rs763589608, COSV100702665; called by muse, varscan2
- TRMT1L | c.610A>T p.R204W | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV100834682; called by muse, mutect2, varscan2
- TRMT61B | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761888934, COSV100066701; called by muse, mutect2, varscan2
- TRO | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV99436907; called by muse, mutect2, varscan2
- TRPC5 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 121/190 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99461925; called by muse, mutect2, varscan2
- TRPM3 | c.1658G>T p.G553V (on ENST00000357533 / NM_001366142.2; = p.G398V on NM_024971.6) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV100677906; called by muse, mutect2, varscan2
- TSHZ3 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99552145; called by muse, mutect2, varscan2
- TSPAN32 | c.497G>C p.G166A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV99478306; called by muse, mutect2
- TSPY2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100289200; called by muse, varscan2
- TTN | c.54135T>A p.N18045K (on ENST00000591111; = p.N10621K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | PolyPhen possibly damaging (0.889); catalogued as COSV100621158, COSV60223492; called by muse, mutect2, varscan2
- TUBA3C | c.71A>T p.Y24F | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.173); catalogued as COSV101262810; called by muse, mutect2, varscan2
- UBAP2 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100671675; called by muse, mutect2, varscan2
- UBE3B | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99784232; called by muse, mutect2, varscan2
- UBR4 | c.12955C>A p.R4319S | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100921331; called by muse, mutect2, varscan2
- UGGT2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100948790; called by muse, mutect2, varscan2
- UGT2B11 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV101485267; called by muse, mutect2, varscan2
- UGT3A1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV57101721, COSV99955059; called by muse, mutect2, varscan2
- UNC5C | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV101497963, COSV71659754; called by muse, mutect2, varscan2
- UNC5D | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99777205; called by muse, mutect2, varscan2
- UNC79 | c.1932C>G p.F644L (on ENST00000393151 / NM_001346218.2; = p.F467L on NM_020818.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.943); catalogued as COSV99828850; called by muse, mutect2, varscan2
- URB2 | c.4492A>G p.R1498G | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99271556; called by muse, mutect2, varscan2
- USH2A | c.13589C>A p.S4530* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV100238676; called by muse, mutect2, varscan2
- USP13 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV99831454; called by muse, mutect2, varscan2
- USP15 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99740120; called by muse, mutect2, varscan2
- USP29 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV99518347; called by muse, mutect2, varscan2
- USP42 | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs767024148, COSV100084893, COSV60357848; called by muse, mutect2, varscan2
- UTP11 | c.381T>A p.D127E | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100884953; called by muse, mutect2, varscan2
- UTP18 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56582733, COSV99834851; called by muse, mutect2, varscan2
- UXS1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99308477; called by muse, mutect2, varscan2
- VCP | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV100734279, COSV62720823; called by muse, mutect2, varscan2
- VEPH1 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100747782; called by muse, mutect2, varscan2
- VIRMA | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV52591274, COSV99888893; called by muse, mutect2, varscan2
- VNN2 | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as COSV100426882, COSV58471449; called by muse, mutect2, varscan2
- WDR26 | c.1971C>G p.D657E (on ENST00000414423 / NM_001379403.1; = p.D557E on NM_025160.7) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as COSV99691371; called by muse, mutect2, varscan2
- WDR43 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.295); catalogued as COSV101333014; called by muse, mutect2
- WFS1 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV99901452; called by muse, mutect2, varscan2
- WNT5B | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100148760; called by muse, varscan2
- WNT8A | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100843070; called by muse, mutect2, varscan2
- WWC2 | c.1972G>T p.V658L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV100968427; called by muse, mutect2, varscan2
333 further variants in this file (71 protein-altering or splice-affecting, 235 silent, 27 other) are not listed here.
